TCGA case TCGA-06-0241 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6d4ab866-ca0b-4455-898e-df8a6ac3e924

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 1,481 days (4.1 years).

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,101 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cilengitide; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 81 days; Number of cycles: 1; Treatment dose: 4,000 mg; Prescribed dose: 2000; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 56 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 81 days; Number of cycles: 1; Treatment dose: 140 mg/day; Prescribed dose: 140; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cilengitide; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 192 days; Number of cycles: 4; Treatment dose: 1,600 mg; Prescribed dose: 2000; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 192 days; Number of cycles: 4; Treatment dose: 390 mg/day; Prescribed dose: 390; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 203 days; Days to treatment end: 799 days (2.2 years); Number of cycles: 20; Treatment dose: 773 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 477 days (1.3 years); Days to treatment end: 728 days (2.0 years); Number of cycles: 17; Treatment dose: 773 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,043 days (2.9 years); Days to treatment end: 1,435 days (3.9 years); Number of cycles: 10; Treatment dose: 822 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 1,267 days (3.5 years); Days to treatment end: 1,277 days (3.5 years); Treatment dose: 3,200 cGy; Course number: 2; Number of fractions: 4; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,324 days (3.6 years); Days to treatment end: 1,383 days (3.8 years); Number of cycles: 3; Treatment dose: 140 mg; Prescribed dose: 100; Prescribed dose units: mg/m2; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 66.5 years (24,297 days); Days to diagnosis: 196 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 66.5 years (24,297 days); Days to diagnosis: 196 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 196 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 196 days.
- Days to follow up: 455 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 1,481 days (4.1 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0241-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-06-0241-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-06-0241-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent necrosis: 5.
- Sample TCGA-06-0241-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0241-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 01.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 02; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 4: Regimen number: 05; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 03; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: Stereotactic Radiosurgery; Therapy regimen: Progression.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,481 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,481 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 196 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0241-01A-02D-0236-01): tumor purity 0.9, ploidy 1.95, whole-genome doublings 0.
